Gene-level copy-number profile of tumor specimen ALCH-B1U4-TTP1-A from ALCHEMIST case ALCH-B1U4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.8 years (27,319 days).
Specimen ALCH-B1U4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a27ba6c5-5c19-4ef6-9b86-5484c77d5a65.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1U4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/49df980a-f675-4142-8e69-d9c5eea713a1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 1,264; copy number 2: 47,260; copy number 3: 9,277; copy number 4: 528; copy number 5: 13; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:45,530,927–45,570,049, 2 genes: HMGB1P48, AKR1A1.
- chr2:89,330,110–89,600,680, 2 genes: IGKV2-40, 5S_rRNA.
- chr3:147,386,046–147,406,809, 2 genes (within-gene range 0–2): ZIC4, ZIC4-AS1.
- chr4:151,027,090–151,104,642, 3 genes (within-gene range 0–2): AK4P6, RPS3A, SNORD73B.
- chr4:151,103,827–151,103,891, 1 gene (within-gene range 0–2): SNORD73A.
- chr10:42,279,734–42,281,819, 1 gene: PABPC1P8.
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.
- chr14:34,568,689–34,569,129, 1 gene (within-gene range 0–2): RPS19P3.
- chr15:71,792,638–71,823,384, 2 genes (within-gene range 0–2): NR2E3, AC104938.1.
- chr17:18,452,955–18,453,739, 2 genes (within-gene range 0–5): AL353997.1, AL353997.4.
- chr17:58,675,286–58,679,690, 3 genes (within-gene range 0–2): AC011195.1, RNU1-52P, RNVU1-34.
- chr19:14,514,769–14,565,980, 2 genes (within-gene range 0–2): DNAJB1, TECR.
- chr19:14,566,078–14,612,035, 4 genes: NDUFB7, CLEC17A, RN7SL337P, RN7SL842P.
- chr19:27,638,483–27,646,483, 2 genes: ERVK-28, AC112702.1.
- chr19:49,506,816–49,526,428, 1 gene: FCGRT.
- chr20:25,985,210–26,114,028, 6 genes: FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1.
- chr20:32,564,992–32,608,893, 2 genes (within-gene range 0–2): NOL4L-DT, AL133343.1.
- chr20:47,348,137–47,412,327, 3 genes (within-gene range 0–2): AL031666.3, AL031666.1, LINC01754.
- chr22:40,673,484–40,682,814, 2 genes: GAPDHP37, MCHR1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,646,230–150,720,895, 3 genes, copy number 5: GOLPH3L, HORMAD1, RNU6-1042P.
- chr2:242,087,351–242,088,457, 1 gene, copy number 5: AC093642.2.
- chr7:76,818,377–76,919,191, 2 genes, copy number 5: AC006972.1, AC007003.1.
- chr9:91,206,175–91,210,299, 1 gene, copy number 5: AL158071.4.
- chr11:66,050,729–66,244,744, 3 genes, copy number 5 (within-gene range 2–5): SF3B2, AP006287.2, PACS1.
- chr12:58,244,378–58,244,865, 1 gene, copy number 5: RPL21P103.
- chr17:18,450,244–18,475,920, 1 gene, copy number 5 (within-gene range 0–5): KRT16P4.
- chr17:18,460,391–18,494,945, 2 genes, copy number 5–6: TNPO1P2, LGALS9C.

Autosomal genes at a single copy (total copy number 1): 1,208. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
